Surgical pathology report (de-identified scan), TCGA case TCGA-55-6975, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-6975-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

Not for Permanent Storage in Medical Records / Not Valid for Signing

Requested by: [REDACTED]

Date of Service: [REDACTED]

Result Provider : [REDACTED]
Report Name :Surgical Report

SEE REPORT [REDACTED]

SURGICAL PATHOLOGY REPORT

PROCEDURE DATE: [REDACTED]

==== SPECIMEN DESCRIPTION: =====

A. LEFT LOWER LOBE OF LUNG, [REDACTED]

==== PRE-OPERATIVE DIAGNOSIS: =====

Left lung mass

==== POST-OPERATIVE DIAGNOSIS: =====

Same, pending pathology

==== CLINICAL INFORMATION: =====

Left lung mass

==== INTRAOPERATIVE CONSULTATION: =====

APC DIAGNOSIS: "Received left lower lobe with a large palpable mass, inked and sectioned; large necrotic mass grossly involves pleural;
1. (Cytosmear) nonsmall cell carcinoma, favor squamous, pending pathology review;
2. (Frozen section) bronchial margin negative for tumor," by [REDACTED]

==== GROSS DESCRIPTION: =====

A. The specimen consists of the left lower lobe, measuring 17 x 13 x 9 cm and weighing 285 grams. The pleural surface is smooth and congested. The medial aspect reveals a portion of adherent pulmonary tissue (possibly from the left upper lobe), measuring 4.0 x 2.5 x 1.7 cm. The adherent tissue has a staple line, measuring 4 cm in length. The specimen is serially sectioned to reveal a well-circumscribed tan-white mass, measuring 6.5 x 6.0 x 6.0 cm. The mass is composed of tan-white firm tissue with focal necrosis. The mass is 1 cm from the bronchial margin. The remaining specimen shows tan-pink spongy pulmonary parenchyma with focal congestion. No sac-like lesion is identified. The bronchial and vascular margins are unremarkable. Three hilar lymph nodes, ranging from 0.6 to 1.0 cm in greatest dimension, are identified. Sections show moderate anthracosis. Representative sections are submitted in nine cassettes as follows: cassette 1 - bronchus at the frozen section piece; cassette 2 - vascular margin; cassette 3 - three hilar lymph nodes; cassette 4 - adherent portion with staple line; cassettes 5 through 7 - mass; cassettes 8 and 9 - lung parenchyma away from the mass.

[REDACTED] The specimen consists of two pieces of tan-white soft tissue, measuring 0.8 x 0.5 x 0.2 cm and 1.5 x 0.5 x 0.2 cm. The specimen is submitted intact in one cassette.

[page 2 of 2]
[REDACTED]

Not for Permanent Storage in Medical Records / Not Valid for Signing

[REDACTED] [REDACTED]

[REDACTED]

==== MICROSCOPIC DESCRIPTION: =====

A. Nine slides are examined. The bronchial margin appears on cassette 1 and does not show any evidence of involvement by tumor. Portions of vascular margin appear on cassette 2 without evidence of tumor involvement. Three hilar lymph nodes are present on slide 3. All of them show extensive replacement by non-oat cell carcinoma. Portions of lung mass are seen on slides 4 through 7. The tumor demonstrates extensive necrosis on slide 4, and the remaining pattern is that of a moderately to poorly differentiated carcinoma with numerous areas showing clear cells along with typical malignant glands. There is extensive intrapulmonary lymphatic and vascular invasion. Pleural lymphatics on slide 4 are filled with plugs of tumor and both veins and lymphatics of the interlobular septum show tumor involvement on the same slide. Extensive involvement of the visceral pleura is also noted on slide 5. On slide 6, there is a focal area showing dyskeratotic cells consistent with squamous differentiation. Focal areas of bronchioalveolar differentiation are noted on slide 6. On slide 7, small areas of vascular involvement are present with plugs of tumor present in endothelial lined spaces. On slide 8, which is said to represent lung tissue taken away from the tumor there appears to be a minute independent focus of poorly differentiated adenocarcinoma.

[REDACTED] One slide is examined. A portion of bronchial wall with cartilage is present. No tumor is seen. This supports the frozen section diagnosis.

[REDACTED]

==== FINAL DIAGNOSIS: =====

A

1. HISTOLOGIC TYPE: ADENOCARCINOMA WITH MINOR AREAS OF SQUAMOUS AND BRONCHIOLOALVEOLAR DIFFERENTIATION
2. HISTOLOGIC GRADE: GII-III
3. EXTENT OF INVASION: pT2
4. MARGINS: VASCULAR AND BRONCHIAL MARGINS CLEAR
5. BLOOD/LYMPHATIC VESSEL INVASION: PRESENT
6. REGIONAL LYMPH NODES: METASTATIC CARCINOMA IDENTIFIED IN THREE OF THREE HILAR LYMPH NODES (pN1)
7. DISTANT METASTASIS: CANNOT EVALUATE
8. ADDITIONAL PATHOLOGIC FINDINGS: PATCHY COPD

A-MALIGNANT

[REDACTED]

Source: NCI Genomic Data Commons file 4ce667a2-abfc-40d9-a5f0-57c0cccdf80f (TCGA-55-6975.7C03CF6A-C871-4C53-AF4D-CB931F6D8B72.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).